Somatic mutation profile of tumor specimen TCGA-25-2398-01A (aliquot TCGA-25-2398-01A-01W-0799-08) from TCGA case TCGA-25-2398, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.9 years (26,267 days).
Specimen TCGA-25-2398-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0e54c97-b4ec-480e-b1dc-30b8459cf219.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-2398-10A (Blood Derived Normal), aliquot TCGA-25-2398-10A-01D-0704-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00be7f02-1b20-4dfa-94ee-135d4a092cc1

The open-access MAF lists 61 somatic variants for this specimen: 41 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 19, Nonsense Mutation 4, Frame Shift Del 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP35 | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101351157; called by muse, varscan2
- ARHGAP35 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101351160; called by muse, varscan2
- ARHGAP35 | c.1756C>T p.Q586* | Nonsense Mutation (SNP) | VAF 48/291 reads (16%) | catalogued as COSV68329637; called by muse, mutect2, varscan2
- CETN1 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as COSV59121006; called by muse, mutect2, varscan2
- CLEC14A | c.795C>G p.D265E | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV60561928; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1238C>T p.T413M | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1385012062, COSV62567000, COSV62570201; called by muse, mutect2, varscan2
- FAM122A | c.647G>A p.R216K | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.953); catalogued as COSV99599020; called by muse, mutect2
- GPR141 | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 104/590 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs766476489, COSV57731549; called by muse, mutect2, varscan2
- GPR142 | c.197G>A p.W66* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV59518799; called by muse, mutect2, varscan2
- IL21R | c.1265G>A p.G422E | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV61968824; called by muse, mutect2, varscan2
- INPP5D | c.437C>G p.S146* (on ENST00000445964 / NM_001017915.3; = p.S145* on NM_005541.5) | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV64035855, COSV64038177; called by muse, mutect2, varscan2
- JCAD | c.2138C>G p.P713R | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.257); catalogued as COSV64758356; called by muse, mutect2, varscan2
- KREMEN1 | c.1256C>T p.S419F (on ENST00000407188; = p.S421F on NM_032045.5) | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); catalogued as rs1410461495, COSV59911803; called by muse, mutect2, varscan2
- MAGI2 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.703); catalogued as rs776534735, COSV62639280; called by muse, mutect2, varscan2
- MAMDC2 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 14/442 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749635558, COSV65858547, COSV65859024; called by muse, mutect2
- MGRN1 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs747300145, COSV52149027; called by muse, mutect2, varscan2
- MUC21 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.075); catalogued as rs766234206, COSV66220370; called by muse, varscan2
- OCA2 | c.1445C>G p.T482S | Missense Mutation (SNP) | VAF 93/246 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62340463; called by muse, mutect2, varscan2
- OR6A2 | c.796C>T p.R266W | Missense Mutation (SNP) | VAF 152/381 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs373299055; called by muse, mutect2, varscan2
- PDE1B | c.1432G>A p.V478M | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54490346; called by muse, mutect2, varscan2
- PFKP | c.1881G>C p.K627N | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66889980; called by muse, mutect2, varscan2
- PROSER1 | c.2390C>G p.P797R | Missense Mutation (SNP) | VAF 33/248 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV61486683; called by muse, mutect2, varscan2
- PSD | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV50042424; called by muse, mutect2
- RBL2 | c.2225C>T p.T742M | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs777931235, COSV50873696; called by muse, mutect2, varscan2
- RGS7 | c.353C>G p.S118* | Nonsense Mutation (SNP) | VAF 14/490 reads (3%) | catalogued as COSV58541248; called by muse, mutect2
- RYR1 | c.239T>A p.M80K | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV62091501; called by muse, mutect2, varscan2
- RYR3 | c.3029A>G p.D1010G | Missense Mutation (SNP) | VAF 57/339 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101212917; called by muse, mutect2, varscan2
- SYNE2 | c.20123A>C p.Q6708P | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV59942148; called by muse, mutect2, varscan2
- TNFRSF9 | c.26T>A p.V9E | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.083); catalogued as COSV66348846; called by muse, mutect2, varscan2
- TRIM10 | c.791G>T p.R264I | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV100939722; called by muse, mutect2
- TRIM40 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 56/918 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV100325380; called by muse, mutect2
- TRMT1 | c.1376C>T p.T459I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as COSV55564817; called by muse, mutect2, varscan2
- TUBB4A | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 60/306 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.505); catalogued as rs745756691, COSV51152512; called by muse, mutect2, varscan2
- YBX1 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV58437431, COSV58437510; called by muse, mutect2, varscan2
- ZNF217 | c.2996G>C p.C999S | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.878); catalogued as COSV56594706, COSV56597808; called by muse, mutect2, varscan2
- ZNF441 | c.1183G>C p.E395Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV63539224; called by muse, mutect2, varscan2
- ZNF776 | c.695G>C p.R232T | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as COSV57814613; called by muse, mutect2, varscan2
- DHX38 | c.967del p.D323Ifs*6 | Frame Shift Del (DEL) | VAF 13/77 reads (17%) | called by mutect2, pindel*, varscan2
- HOMEZ | c.1315C>A p.P439T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- LAMC1 | c.3619dup p.T1207Nfs*4 | Frame Shift Ins (INS) | VAF 39/263 reads (15%) | called by mutect2, pindel, varscan2
- PCSK7 | c.1101del p.C367Wfs*20 | Frame Shift Del (DEL) | VAF 30/150 reads (20%) | called by mutect2, pindel, varscan2
- A2ML1 | c.921G>A p.A307= | Silent (SNP) | VAF 59/496 reads (12%) | catalogued as rs372520121; called by muse, mutect2, varscan2
- ALPK2 | c.3867C>T p.A1289= | Silent (SNP) | VAF 51/267 reads (19%) | catalogued as rs781369958, COSV64490877; called by muse, mutect2, varscan2
- ARHGAP35 | c.768C>T p.I256= | Silent (SNP) | VAF 18/232 reads (8%) | catalogued as COSV101351143; called by muse, mutect2
- ARMCX2 | c.435G>A p.V145= | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as rs782329599, COSV57529426; called by muse, mutect2, varscan2
- FBXO15 | c.1437G>T p.L479= | Silent (SNP) | VAF 215/1663 reads (13%) | catalogued as COSV54043304; called by muse, mutect2, varscan2
- IMPDH2 | c.237C>T p.A79= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs1234449456; called by muse, varscan2
- INO80 | c.4137C>T p.D1379= | Silent (SNP) | VAF 47/148 reads (32%) | catalogued as COSV62736563; called by muse, mutect2, varscan2
- MTIF3 | c.483G>T p.L161= | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as rs138161348; called by muse, mutect2, varscan2
- MUC21 | c.6G>A p.K2= | Silent (SNP) | VAF 29/258 reads (11%) | catalogued as COSV66220363; called by muse, mutect2, varscan2
- NPR1 | c.2025G>A p.K675= | Silent (SNP) | VAF 88/279 reads (32%) | catalogued as COSV64117365; called by muse, mutect2, varscan2
- PIK3IP1 | c.711G>C p.V237= | Silent (SNP) | VAF 74/93 reads (80%) | catalogued as COSV53223142; called by muse, mutect2, varscan2
- SENP7 | c.2589C>T p.L863= | Silent (SNP) | VAF 15/131 reads (11%) | catalogued as rs768736955, COSV58609102; called by muse, mutect2, varscan2
- TIMELESS | c.2268T>C p.S756= | Silent (SNP) | VAF 27/217 reads (12%) | catalogued as COSV57509602; called by muse, mutect2, varscan2
- TRIM10 | c.1215G>A p.V405= | Silent (SNP) | VAF 8/123 reads (7%) | catalogued as rs1022914526, COSV100939721; called by muse, mutect2
- TRPV5 | c.904C>A p.R302= | Silent (SNP) | VAF 85/335 reads (25%) | catalogued as COSV54683675, COSV54686970; called by muse, mutect2, varscan2
- ZBTB8A | c.225T>A p.T75= | Silent (SNP) | VAF 13/280 reads (5%) | called by muse, mutect2
- ZGPAT | c.924T>C p.S308= | Silent (SNP) | VAF 14/208 reads (7%) | catalogued as COSV100203181; called by muse, mutect2
- ZNF212 | c.1452G>A p.L484= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV60024675; called by muse, mutect2, varscan2
- ZNF611 | c.1821A>T p.S607= | Silent (SNP) | VAF 148/725 reads (20%) | catalogued as rs756158524, COSV60539779; called by muse, mutect2, varscan2
- THSD4 | c.1016-70041G>T | Intron (SNP) | VAF 156/483 reads (32%) | called by muse, mutect2, varscan2
